Somatic mutation profile of tumor specimen MP2PRT-PAVPRT-TMP1-A (aliquot MP2PRT-PAVPRT-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVPRT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,677 days).
Specimen MP2PRT-PAVPRT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f789e4b7-c038-4d19-ad9c-fe3e1bc1af14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPRT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPRT-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfff365d-e997-4404-a850-5e3282a0670f

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CROCC2 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as rs377492526; called by muse, mutect2, varscan2
- FAM181A | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 22/508 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs371120548; called by muse, mutect2
- MEGF10 | c.2569G>A p.G857R | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs748159770, COSV57257500; called by muse, mutect2, varscan2
- POTEE | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 71/542 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100389468, COSV58225660; called by muse, mutect2, varscan2
- GATM | c.1072C>A p.L358I | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HYDIN | c.13198T>C p.S4400P | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR1N2 | c.372C>G p.D124E | Missense Mutation (SNP) | VAF 19/405 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF511 | c.148T>C p.F50L | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SHISA3 | c.291C>T p.V97= | Silent (SNP) | VAF 60/254 reads (24%) | called by muse, mutect2, varscan2
